Surgical pathology report (de-identified scan), TCGA case TCGA-60-2724, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Roswell Park, specimen TCGA-60-2724-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT

SPECIMEN(S): A. 4R LYMPH NODE
B. LEVEL 7 LYMPH NODE
C. RIGHT CARINAL PNEUMONECTOMY
D. LEVEL 7 LYMPH NODE
E. LEVEL 9 LYMPH NODE

CLINICAL HISTORY:

None provided

PRE-OPERATIVE DIAGNOSIS:

SCC of the lung

INTRAOPERATIVE CONSULTATION DIAGNOSIS:

FSA/TPA: Lymph node, 4R, excision: No malignancy identified. By [REDACTED] called [REDACTED]

FSB/TPB: Lymph node, level 7, excision: No malignancy identified. [REDACTED]

FSC1: Inferior bronchial margin: Negative for tumor.

FSC2: Lateral bronchial margin: Negative for tumor with focal mild squamous dysplasia.

Comment: Superior margin is 1.5 cm from the tumor. Grossly negative for tumor.

GROSS DESCRIPTION:

A. 4R

Received fresh for frozen section are two tan-pink fragments of fibrofatty tissue 0.3 x 0.2 x 0.2 cm and 0.1 x 0.1 x 0.1 cm. The larger tissue fragment is bisected. One touch prep is taken and the specimen is submitted in toto for frozen section in FSA1.

B. LEVEL 7 LYMPH NODE

[page 2 of 4]
[REDACTED]

Received fresh for frozen section is a tan-pink lymph node 0.4 x 0.2 x 0.1 cm. The specimen is submitted entirely for frozen section in FSB1. Touch preps are taken.

[REDACTED]

C. RIGHT CARINAL PNEUMONECTOMY

Received fresh for frozen section diagnosis is a right carinal pneumonectomy specimen containing all three lobes and portion of main bronchus measuring 24 x 17 x 6 cm with the weight of 882 gm. The right main bronchus is identified measuring 3.0 cm in the greatest diameter. The right main bronchus shows a 6.0 x 4.5 x 4.0 cm gray-tan, firm and discrete mass. No necrosis or hemorrhage is grossly identified in the tumor. The pleural surface is grossly uninvolved by the tumor. The inferior and lateral bronchus margin is taken for frozen section diagnosis. The specimen is inked externally. Cutting through the lung reveals the tumor involves the middle lobe and portion of the upper lobe. No tumor mass is grossly identified in the lower lobe. Also identified away from the main tumor is a 3.5 x 2.5 x 2.5 cm necrotic area in the upper lobe. The necrotic area is approximately 2.0 cm away from the main tumor. A 4.0 x 3.0 x 2.0 cm hemorrhagic area is also identified in the upper lobe, superior to the necrotic area. Multiple subpleural blebs are identified in the upper lobe. Also noted that the parenchyma in the upper lobe shows diffuse firm change compared to the lower lobe and middle lobe. Multiple presumptive peribronchial lymph nodes are identified from specimen. Representative sections are submitted for microscopic examination as follows:

- C1: frozen section resubmitted for the inferior bronchial margin
- C2: frozen section resubmitted for the lateral bronchial margin
- C3: superior bronchial margin
- C4-C9: representative sections from tumor
- C10-C11: representative sections of the necrotic area in upper lobe
- C12-C13: representative section showing the hemorrhage area in upper lobe
- C14: representative section showing the subpleural blebs
- C15-C16: representative section of the upper lobe
- C17: representative section of the middle lobe
- C18: representative section of the lower lobe
- C19: multiple peribronchial lymph nodes from the upper lobe
- C20-C22: peribronchial lymph nodes from the middle lobe
- C23-C24: peribronchial nodes from the lower lobe
- [REDACTED]

D. LEVEL 7 LYMPH NODE

Received in formalin is anthracotic lymph node measuring 2 x 0.8 x 0.6 cm. Submitted entirely in cassette D1.

E. LEVEL 9 LYMPH NODE

Received in formalin is a red-tan lymph node measuring in 1.1 x 0.7 x 0.3 cm. Bisected and submitted entirely in cassette E1.

[REDACTED]

[page 3 of 4]
DIAGNOSIS:

- A. LYMPH NODE, 4R, EXCISION:
- TWO REACTIVE LYMPH NODES NEGATIVE FOR TUMOR (0/2).
- B. LYMPH NODE, LEVEL 7, EXCISION:
- ONE REACTIVE LYMPH NODE NEGATIVE FOR TUMOR (0/1).
- C. LUNG, RIGHT, CARINAL, PNEUMONECTOMY:
- MODERATELY DIFFERENTIATED SQUAMOUS CELL CARCINOMA OF THE RIGHT MAIN BRONCHUS MEASURING 6 X 4.5 X 4 CM.
- BRONCHIAL MARGIN IS FREE OF TUMOR.
- BRONCHIOPNEUMONIA AND EXTENSIVE NECROSIS AND INTRABRONCHIAL HEMORRHAGE.
- PERIBRONCHIAL LYMPH NODES POSITIVE FOR CARCINOMA (3/39)
- SEE SYNOPTIC REPORT.
- D. LYMPH NODE, LEVEL 7, EXCISION:
- ONE REACTIVE LYMPH NODE (0/1).
- E. LYMPH NODE, LEVEL 9, EXCISION:
- ONE REACTIVE LYMPH NODE (0/1).

SYNOPTIC REPORT - LUNG

Surgical Procedure: Pneumectomy
Laterality: Right
Tumor Site: Right main stem bronchus
Tumor Location: Central
Tumor Size: Greatest diameter: 6cm
Additional dimensions: 4.5cm x 4cm

WHO CLASSIFICATION

Squamous cell carcinoma
Histologic Grade: G2: Moderately differentiated
Angiolymphatic Invasion: Absent
Bronchial Margins: Bronchial margins uninvolved
Tumor Distance from margin: 0.2cm
Visceral Pleural Involvement: Absent
Satellite Tumor(s): Absent
Lymph Node Involvement: N1: Ipsilateral Hilar and/or Peribronchial (levels 10-14)
Positive 3 / 39
N2: Ipsilateral Mediastinal and/or Subcarinal (Levels 1-9)
Negative 0 / 5
Non-Neoplastic Lung: Emphysematous changes
Pneumonia
Hemorrhage
Additional Pathologic Findings: None identified

[page 4 of 4]
[REDACTED]

Pathological Staging (pTNM):

pT3 N1 M X

[REDACTED]

Source: NCI Genomic Data Commons file d229d55c-b056-4d5f-9129-f7789029fd56 (TCGA-60-2724.7A4D6104-67C3-4CBC-AB20-34BABE747ABA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).